Somatic mutation profile of tumor specimen C3L-00011-01 (aliquot CPT0001340005) from CPTAC case C3L-00011, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.8 years (23,307 days).
Specimen C3L-00011-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbe0d9e1-c757-46a1-9720-2dd6ac06a665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00011-31 (Blood Derived Normal), aliquot CPT0000090163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81496bc5-7f16-4ce4-b30d-11522e1fc446

The open-access MAF lists 74 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Intron 8, Nonsense Mutation 4, 3'UTR 3, Frame Shift Del 3, Splice Site 2, 5'Flank 2, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 232/499 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ATG7 | c.906del p.G303Dfs*15 | Frame Shift Del (DEL) | VAF 43/106 reads (41%) | catalogued as COSV100607091; called by mutect2, pindel, varscan2
- COL4A5 | c.5035C>T p.Q1679* | Nonsense Mutation (SNP) | VAF 90/200 reads (45%) | catalogued as CM940312, COSV100086098; called by muse, varscan2
- EP400 | c.5819G>A p.R1940H | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs773564187; called by muse, mutect2, varscan2
- FAM117A | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781624561; called by muse, mutect2, varscan2
- FFAR1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs759823354; called by muse, mutect2, varscan2
- HES1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.077); catalogued as COSV99220375; called by muse, mutect2, varscan2
- NOG | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV60447185; called by muse, mutect2, varscan2
- PACS2 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV57657528; called by muse, mutect2, varscan2
- PCBP1 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.238); catalogued as rs200188120; called by muse, mutect2, varscan2
- PRRG2 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV55870969; called by muse, mutect2
- RAPGEF2 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as rs755809310; called by muse, mutect2, varscan2
- RGS9 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs769963081, COSV99287775; called by muse, mutect2, varscan2
- SLC17A1 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765693; called by muse, mutect2, varscan2
- SORCS3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756722144; called by muse, mutect2, varscan2
- TCEA1 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1255362812; called by muse, mutect2, varscan2
- TGFB1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV54684212; called by muse, mutect2, varscan2
- VHL | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs869025659, CM023999, CS951541, COSV56543854, COSV56544010, COSV56545833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YJEFN3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1415535882; called by muse, mutect2, varscan2
- ZNF469 | c.4477G>A p.G1493R (on ENST00000437464; = p.G1521R on NM_001367624.2) | Missense Mutation (SNP) | VAF 232/985 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs1005974582; called by muse, mutect2, varscan2
- ABCC12 | c.3980T>C p.M1327T | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ACTN3 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ASPM | c.4065+1G>T p.X1355_splice | Splice Site (SNP) | VAF 3/53 reads (6%) | called by muse, mutect2
- ATP1A1 | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.923); called by muse, varscan2
- BICRA | c.656del p.N219Mfs*55 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- CACNA2D4 | c.2996-2A>G p.X999_splice | Splice Site (SNP) | VAF 109/303 reads (36%) | called by muse, mutect2, varscan2
- CFAP46 | c.5675C>G p.A1892G | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CNTNAP1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- EYA1 | c.1384dup p.E462Gfs*11 | Frame Shift Ins (INS) | VAF 144/520 reads (28%) | called by mutect2, pindel, varscan2
- FAM214A | c.2541T>G p.S847R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGFR1OP2 | c.219C>G p.N73K | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLYWCH1 | c.1505G>T p.G502V (on ENST00000253928 / NM_001308068.2; = p.G501V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GLDC | c.1028T>C p.M343T | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- GTF3C1 | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ITPRIPL2 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KCNK16 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM5C | c.1151del p.G384Afs*46 | Frame Shift Del (DEL) | VAF 193/440 reads (44%) | called by mutect2, pindel, varscan2
- KLHL36 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- NR3C1 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 124/609 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PADI1 | c.350T>G p.I117S | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- POGLUT3 | c.606T>G p.H202Q | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RELN | c.8512C>A p.Q2838K | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLF1 | c.1211T>A p.V404D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TM4SF20 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- USP17L2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 113/392 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, varscan2
- USP38 | c.2014C>G p.L672V | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCCHC2 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- CEBPB | c.957G>A p.Q319= | Silent (SNP) | VAF 159/638 reads (25%) | catalogued as rs1237527159; called by muse, mutect2, varscan2
- DENND3 | c.1717C>T p.L573= | Silent (SNP) | VAF 143/390 reads (37%) | called by muse, mutect2, varscan2
- FRMPD3 | c.3573T>G p.S1191= | Silent (SNP) | VAF 100/177 reads (56%) | called by muse, mutect2, varscan2
- IGFBP4 | c.207G>A p.V69= | Silent (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- IRX3 | c.247C>T p.L83= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1332822791; called by muse, varscan2
- KLHL21 | c.345G>A p.L115= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as rs772194747, COSV66553389; called by muse, mutect2
- OR10S1 | c.681C>T p.L227= | Silent (SNP) | VAF 56/198 reads (28%) | catalogued as COSV73342751; called by muse, mutect2, varscan2
- RANBP3L | c.573A>C p.A191= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.76689T>C p.G25563= (on ENST00000591111; = p.G18139= on NM_003319.4) | Silent (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- UNC45A | c.1446G>A p.L482= | Silent (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- ZDHHC13 | c.1704G>A p.T568= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs563409613; called by muse, mutect2, varscan2
- ZNF280B | c.858T>C p.S286= | Silent (SNP) | VAF 77/258 reads (30%) | catalogued as rs1365026790, COSV64528824; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501090 G>A | 5'Flank (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CHIT1 | c.*459G>A | 3'UTR (SNP) | VAF 95/341 reads (28%) | called by muse, mutect2, varscan2
- GYS1 | c.*158G>T | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- HIVEP1 | c.40+4739C>A | Intron (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- HSF4 | c.1255-20T>G | Intron (SNP) | VAF 272/554 reads (49%) | called by muse, mutect2, varscan2
- PDE2A | c.144+6255G>A | Intron (SNP) | VAF 34/116 reads (29%) | catalogued as rs765358212; called by muse, mutect2, varscan2
- PKM | c.-14+140C>G | Intron (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- POLR1C | c.922+23A>G | Intron (SNP) | VAF 151/486 reads (31%) | called by muse, mutect2, varscan2
- PSMD1 | c.-97G>A | 5'UTR (SNP) | VAF 13/201 reads (6%) | catalogued as rs1489138846; called by muse, mutect2
- SLCO1A2 | c.61-455G>A | Intron (SNP) | VAF 60/267 reads (22%) | catalogued as rs758922924, COSV56597878; called by muse, mutect2, varscan2
- SNCB | c.163+69C>T | Intron (SNP) | VAF 58/301 reads (19%) | catalogued as rs1403582616, COSV59434839; called by muse, mutect2, varscan2
- THBD | c.*30C>G | 3'UTR (SNP) | VAF 23/82 reads (28%) | catalogued as rs1380198920; called by muse, mutect2, varscan2
- TOMM7 | c.103+439A>C | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- VEGFA | chr6:43770958 C>G | 5'Flank (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- ZNF849P | n.1043G>T | RNA (SNP) | VAF 50/176 reads (28%) | catalogued as rs1230340712; called by muse, mutect2, varscan2
